Surgical pathology report (de-identified scan), TCGA case TCGA-OU-A5PI, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site Roswell Park, specimen TCGA-OU-A5PI-01A (Primary Tumor).

[page 1 of 4]
ICD-O-3
Carcinoma, Adrenal
Cortical 8370/3
Site: Adrenal Gland, cortex
C74.0

QAD 2/1/13

- SPECIMEN(S):**
- A. PORTION OF 10TH RIB
- B. LEFT KIDNEY AND ADRENAL GLAND
- C. PARA AORTIC LYMPH NODE
- D. RIGHT LOWER LOBE LUNG WEDGE RESECTION
- E. RIGHT LOWER LOBE NODULE/WEDGE #2
- F. RIGHT MIDDLE LOBE NODULE/WEDGE

CLINICAL HISTORY:

PRE-OPERATIVE DIAGNOSIS:

GROSS DESCRIPTION:

A. PORTION OF 10TH RIB

Received fresh with patient's identification and designated "portion of 10th rib" are 2 tan pink bone segments, 3.2 x 1.2 x 0.5 cm and 4 9 x 1.2 x 1 cm, show no grossly visible lesions, representatively submitted in cassette A1, following decalcification.

B. LEFT KIDNEY AND ADRENAL GLAND

Received fresh with patient's identification and designated "left kidney and adrenal gland" is a left kidney with peri renal fat and the attached adrenal gland, weighing 1243 g, with overall measurements of 24.0 x 9.5 x 8.5 cm (the kidney measures 10.5 x 7.5 x 4.5 cm, the adrenal gland measures 13.5 x 9.5 x 8.5 cm). The specimen is inked blue. The attached segment of ureter measures 3 cm in length, 0.5 cm in diameter, the renal vein measures 1 cm in length, 0.5 cm in diameter and the renal artery measures 1 cm in length by, 0.3 cm in diameter. Upon bivalving the specimen, the kidney shows tan-brown cortex with a well defined cortico-medullary junction. The pelvis and calyces are covered by smooth, glistening mucosa and shows no grossly visible lesions/masses. The attached adrenal gland is diffusely enlarged, grossly appears to encroach on to the kidney, with no grossly visible invasion and shows, variegated and hemorrhagic cut surface.

Examination of the peri renal fat reveals no grossly visible nodes/masses.

Examination of the soft tissue and fat around the adrenal gland shows 9 tan-white to tan-pink, firm to hard nodes, 0.3 x 0.2 x 0.2 cm to 1.5 x 1.3 x 1.2 cm.

Gross pictures of the specimen taken and specimen submitted for procurement.
Representatively submitted in 27 cassettes as follows:

B1= Ureter & blood vessels

B2-B5 = sections of kidney including renal pelvis.

B6-B7 = sections of kidney with attached adrenal gland

[page 2 of 4]
B8-B20 = random sections of the enlarged adrenal gland

B21-B22 = random sections of the perirenal fat

B23-B27 = nodules near the adrenal gland (B23 - 5 nodules, B24 - 2 nodules, B25-B27 - bisected single nodes)

B28-B32 = additional sections of tumor and capsule

C. PARA AORTIC LYMPH NODE

Received fresh with patient's identification and designated "parotid lymph node" is a tan-white to tan-pink, fibro fatty soft tissue fragment, 4.4 x 4.2 x 1.9 cm. The attached fat measures 2.2 x 3.2 x 0.8 cm in aggregate. The specimen is inked with black ink and the cut section reveals 2 tan-pink, soft to firm lymph nodes, 3.2 x 2.2-1.2 and 3.8 x 2.3 x 2.1 cm, grossly appear to be matted. Examination of the attached fatty tissue reveals a tan-pink, firm to hard possible lymph node, 1.2 x 0.9 x 0.6 cm. Representative section of the matted lymph nodes and the bisected, entire smaller lymph node submitted in 4 cassettes as follows:

C1-C3 = full-thickness section of the matted lymph nodes,

C4 = bisected smaller lymph node.

D. RIGHT LOWER LOBE LUNG WEDGE RESECTION

Received fresh with patient's identification and designated "right lower lobe lung wedge resection" is a lung wedge, 35.8 g, and 9 X 4.5 x 3 cm.

Frozen section analysis was performed and reported as poorly differentiated carcinoma, favor metastasis.

The pleural surface is tan-pink without any grossly visible lesions. The stapled margin is inked blue and the pleural surface is inked black. Serial sectioning of the specimen after removal of the stapled margin reveal a tan-white, firm to hard nodule, 1.5 x 1.5 x 1 cm, seen located 1 cm from the resection margin. Representatively submitted in 6 cassettes as follows:

D2-D3 = sections from the nodule

D4-D5 = sections from the adjacent lung parenchyma

D6-D7 = sections from the normal appearing lung parenchyma

E. RIGHT LOWER LOBE NODULE/WEDGE #2

Received fresh with patient's identification and designated "right lower lobe nodule/wedge #2" is a lung wedge, 2 g, 4.2 X 1.2 x 0.3 cm. The pleural surface is tan-pink without any grossly visible lesions. The stapled margin is inked blue and the pleural surface inked black. Serial sectioning of the specimen after removal of the stapled margin reveal a tan-white to tan-pink, area 0.3 x 1.2 cm seen located 0.2 cm from the resection margin. Submitted entirely in 3 cassettes, E1-E3.

F. RIGHT MIDDLE LOBE NODULE/WEDGE

Received fresh with patient's identification and designated "right middle lobe nodule/wedge" is a lung wedge, 35.8 g, 9 x 4.5 x 3 cm. The pleural surface is tan-pink without any grossly visible lesions. The stapled margin is inked blue and the pleural

[page 3 of 4]
surface is inked black. Serial sectioning of the specimen after removing the stapled margin reveals a tan-pink to tan-white, rubbery, firm to hard nodule, 1.1 x 0.9 x 0.3 cm is seen located 1 cm from the resection margin. Representatively submitted in 6 cassettes as follows:

F1-F2 = sections from the nodule

F3-F4 = sections from the adjacent lung parenchyma

F5-F6 = sections from the normal appearing lung parenchyma

DIAGNOSIS:

A. BONE, 10TH RIB, EXCISION:

- BONE AND BONE MARROW SHOWING TRILINEAGE HEMATOPOIESIS.
- NO MALIGNANCY IDENTIFIED.

B. LEFT KIDNEY AND ADRENAL GLAND, NEPHRECTOMY AND ADRENALECTOMY:

ADRENAL GLAND:

- ADRENAL CORTICAL CARCINOMA, 126 GRAMS.
- TUMOR SIZE: 13.5 X 9.5 X 8.5 CM
- 8 MITOSES/10 HPF WITH ABNORMAL MITOSIS
- PROLIFERATION INDEX (KI67): 10%
- TUMOR FOCALLY INFILTRATES THE PERIADRENAL ADIPOSE TISSUE AND MULTIPLE DISCREET PERIADRENAL TUMOR

NODULES

- PROMINENT TUMOR NECROSIS IS PRESENT.
- CAPSULAR INVASION IS PRESENT
- CELLULAR PLEOMORPHISM: MODERATE
- VASCULAR INVASION: INDETERMINATE.
- TUMOR IS 1 MM FROM THE INKED MARGIN OF RESECTION.

KIDNEY:

- NO INVASION OF KIDNEY BY THE ADRENAL TUMOR.

C. LYMPH NODE, PARA AORTIC, EXCISION:

- POSITIVE FOR MALIGNANCY (3/3).

D. LUNG, RIGHT LOWER LOBE, WEDGE RESECTION:

- METASTATIC CARCINOMA CONSISTENT WITH ADRENAL PRIMARY.
- TUMOR LOCATED 1 CM FROM THE PARENCHYMAL MARGIN

E. LUNG, RIGHT LOWER LOBE NODULE, WEDGE RESECTION:

- METASTATIC CARCINOMA CONSISTENT WITH ADRENAL PRIMARY.
- TUMOR LOCATED 0.2 CM FROM THE PARENCHYMAL MARGIN

F. LUNG, RIGHT LOWER LOBE NODULE, WEDGE RESECTION:

[page 4 of 4]
- METASTATIC CARCINOMA CONSISTENT WITH ADRENAL PRIMARY.
- TUMOR LOCATED 1 CM FROM THE PARENCHYMAL MARGIN

SUMMARY OF IMMUNOHISTOCHEMISTRY/SPECIAL STAINS

Material: Block B12

Population: Tumor Cells

Stain/Marker:	Result:	Comment:
MIB1-Ki67	10 % Positive Cells	
INHIBIN-ALPHA	Positive	Focal
A103,MELAN-A	Positive	Focal, Weak
CHROMOGRANIN A	Negative	
S-100	Negative	
CD 10	Negative	

The interpretation of the above immunohistochemistry stain or stains is guided by published results in the medical literature, provided package information from the manufacturer and by internal review of staining performance and assay validation within the Immunohistochemistry Laboratory of the Department of Pathology Laboratory at [redacted]. The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR). These tests were developed and their performance characteristic determined by the Department of Pathology Laboratory at [redacted]. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

Special stains and/or immunohistochemical stains were performed with appropriately stained positive and negative controls.

ADDENDUM:

Frozen section results were omitted for part D and are as follows:

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSD: Lung, right lower lobe, resection: Poorly differentiated carcinoma, favor metastasis. Called to the O.R.

Criteria	W 1/30/13	Yes	No
IHPAA Discrepancy			/

Source: NCI Genomic Data Commons file 4042ee5b-cdd9-4bb3-bb08-793ad5cedc42 (TCGA-OU-A5PI.2AA8FA9B-A202-48AB-A543-6E0B1B45B1D4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).